Gene-level copy-number profile of tumor specimen C3N-00857-01 (profiled together with C3N-00857-02) from CPTAC case C3N-00857, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 64.5 years (23,545 days).
Specimen C3N-00857-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0e6dfa7f-194f-4b63-b769-c7e7d77ebf38.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00857-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/9bd50afe-3840-4267-a52e-474d4370f629

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 504; copy number 1: 30; copy number 2: 11,128; copy number 3: 21,021; copy number 4: 9,081; copy number 5: 11,072; copy number 6: 1,649; copy number 7: 1,747; copy number 8: 365; copy number 9: 163; copy number 10: 417; copy number 11: 930; copy number 12: 100; copy number 13: 38; copy number 15: 13; copy number 16: 69; copy number 17: 442; copy number 18: 11; copy number 19: 5; copy number 22: 59; copy number 28: 1; copy number 32: 11; copy number 35: 5; copy number 36: 17; copy number 64: 8; copy number 74: 21.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,422 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:142,912,116–184,017,939, 602 genes, copy number 7–74 (within-gene range 5–74) (broad region; genes not listed).
- chr3:184,026,369–198,123,232, 331 genes, copy number 7 (broad region; genes not listed).
- chr5:181,306,502–181,324,685, 1 gene, copy number 19: AC138035.1.
- chr6:55,106,460–55,875,590, 5 genes, copy number 8: HCRTR2, GFRAL, HMGCLL1, AL590290.1, BMP5.
- chr7:37,032–118,004,045, 2,090 genes, copy number 7–64 (broad region; genes not listed).
- chr8:36,378,069–39,867,812, 82 genes, copy number 7–12 (broad region; genes not listed).
- chr9:61,190,003–61,911,022, 19 genes, copy number 8: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2, RN7SL722P, AL391987.2, AL391987.1, AL391987.4, AL391987.3, Y_RNA, FAM242E.
- chr9:63,581,254–64,082,534, 15 genes, copy number 8: AL591438.1, AL591438.2, CDRT15P7, AL772155.1, AL772155.2, MYO5BP3, CDK2AP2P3, PTGER4P3, CR786580.1, RNA5SP284, DUX4L50, MIR4477B, FRG1JP, AL163540.1, U6.
- chr11:68,754,620–71,423,423, 62 genes, copy number 11–28 (broad region; genes not listed).
- chr12:12,310–34,249,958, 834 genes, copy number 8–12 (broad region; genes not listed).
- chr19:11,199,295–11,262,524, 1 gene, copy number 7 (within-gene range 3–7): DOCK6.
- chr19:11,237,450–17,590,071, 380 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
